Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A7CF, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A7CF-02A (Recurrent Tumor).

[page 1 of 2]
DOB :
Sex :

HISTOPATHOLOGY REPORT

CLINICAL NOTES:

History of right insular low grade astrocytoma (grade 2). Now with recurrence. No prior XRT or chemo.

MACROSCOPIC:

'Brain tumour'. The specimen consists of multiple pieces of tan soft tissue ranging between 5mm and 50mm in maximum dimension. The largest piece is 50x40x20mm and has two slightly expanded appearing gyri with leptomeninges. The second largest piece is 30x18x15mm with a smooth leptomeningeal surface. The largest piece shows a well defined grey/white junction on the cut surface. This is blurred on the cut surface of the second largest piece. Representative sections; approximately 40% of material embedded. (Blocks A to D - second largest piece, E to H - largest piece, I and J - smaller pieces) BE4

MICROSCOPIC:

STRUCTURED REPORT FOR TUMOURS OF THE CENTRAL NERVOUS SYSTEM

Adapted from Tumours of the Central Nervous System Structured Reporting Protocol based on WHO classification 2007, 4th Edition. First Edition 2011.

CLINICAL SUMMARY:

Date of Birth/Age:

Sex:

Requesting Clinician:

Treating Clinician(s):

Clinical history on request form:

Ancillary tests requested:

Other clinical history-source:

Presenting symptoms:

Duration of symptoms:

Previous tumour history:

Current and previous treatment:

Family history:

Imaging findings:

Anatomical site of lesion/s:

Laterality of tumour:

Reason for biopsy:

Clinical diagnosis or differential diagnosis:

Unknown

History of right insular low grade astrocytoma (grade 2) now with recurrence. No prior XRT or chemo.

P53, EGFR, MGMT, LOH1P/19Q, Ki67, IDH1

Previous pathology report from

Unknown

Unknown

Previous low grade astrocytoma, grade II

No previous treatment

Unknown

Unknown

Presumed to be right insular region

Presumed to be right

Recurrence

Unknown

MACROSCOPIC SPECIMEN SUMMARY:

Specimen type(s):

Number of specimens:

Dimensions:

Specimen received in:

Triage of fresh tissue:

Amount of unprocessed tissue: 60%

Resection

Multiple

50x40x20mm and 30x18x15mm

Formalin

N/A

ICD O 3
Astrocytoma, grade III
Site Brain, supratentorial NOS
C71.0
Brain, mole C71.0
9/25/13

Surge
Use

Norm

No-Actu
File

Conta
Patier

See
Patier

See Fi

Contin
Treatm

Signe

Date

Tests Completed: Histo. FINAL REPORT

Clinical Notes:

Page 1 of 2

[page 2 of 2]
MICROSCOPIC FEATURES:

Microscopic description:

The sections show a cellular astrocytic tumour which displays pleomorphic nuclei and there are mitoses present, numbering in one section, up to 3 per 10 high power fields. There is no endothelial proliferation and there is no necrosis.

Proliferation index (Ki67): 2%
p53: 40%
IDH1: 1 positive
Mitoses: 3/10HPF
Specimen comment: Diagnostic

IMMUNOHISTOCHEMICAL STAINS:

Positive: Block: A
IDH1

MOLECULAR PATHOLOGY AND OTHER TESTING IF REQUIRED:

FISH 1p 19q and EGFR amplification: Awaiting patient agreement
MGMT promoter methylation: Block: A
IDH1/IDH2 exon 4 sequencing: N/A
Clinical trials (with ethics): Block: A
Research block requests with ethics approval when no longer required for diagnosis: Block: A

Note: Any further results will be issued as a supplementary report.

LINEAGE: Astrocytic

OVERALL COMMENT/SUMMARY: The histological features are those of an anaplastic astrocytoma

DIAGNOSTIC SUMMARY:

Specimen type: Resection
Tumour site and laterality: Presumed right insular region
WHO 2007 tumour type: Anaplastic astrocytoma
WHO 2007 grade: III
Differential diagnosis: Nil

ICD-O-3 CODE: 94013

DIAGNOSIS: ANAPLASTIC ASTROCYTOMA, GRADE III

DIAGNOSIS:

BRAIN TUMOUR - ANAPLASTIC ASTROCYTOMA, GRADE III

Reported by

Surge Use
Norm
No-Actv File
Conta Patier
See Patier
See Fi
Contn Treatm
Signe
Date

Recurrence
Primary astrocytoma II dx'ed
BCR

Tests Completed: Histo. **FINAL REPORT**

Clinical Notes:

Source: NCI Genomic Data Commons file 055c7242-e657-4080-b33b-d597c9a66b26 (TCGA-TM-A7CF.E7D22CFE-C4C9-4E2F-AB45-713180E95C00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).